Somatic mutation profile of tumor specimen C3N-02998-03 (aliquot CPT0187930008) from CPTAC case C3N-02998, project CPTAC-3 (Pancreas — Ductal and Lobular Neoplasms). Sex at birth: female; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage III; Tumor grade: G2; Age at diagnosis: 65.0 years (23,734 days).
Specimen C3N-02998-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Pancreas; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 67e06982-cc78-4c17-88d2-fcebc7d5cfa1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-02998-31 (Blood Derived Normal), aliquot CPT0187950002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ff078edd-6cad-4ab6-a6fc-7a0d57fa33ff

The open-access MAF lists 21 somatic variants for this specimen: 10 protein-altering or splice-affecting, 5 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 9, Silent 5, Intron 3, RNA 2, 3'UTR 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SMARCA4 | c.3566G>A p.R1189Q | Missense Mutation (SNP) | VAF 28/939 reads (3%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60788908, COSV60805381; called by muse, mutect2
- KRTAP9-7 | c.422G>A p.R141H | Missense Mutation (SNP) | VAF 21/666 reads (3%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.493); catalogued as rs552638863; called by muse, mutect2
- OR2J1 | c.427C>T p.R143C | Missense Mutation (SNP) | VAF 13/308 reads (4%) | SIFT tolerated (0.18); PolyPhen benign (0.001); catalogued as rs536457657; called by muse, mutect2
- PIK3C2G | c.169G>A p.E57K | Missense Mutation (SNP) | VAF 13/336 reads (4%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.003); catalogued as rs1251272146; called by muse, mutect2
- PLEC | c.5831G>A p.R1944H (on ENST00000322810 / NM_201380.4; = p.R1834H on NM_000445.5) | Missense Mutation (SNP) | VAF 17/514 reads (3%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs782737003; ClinVar: likely benign; called by muse, mutect2
- EVX1 | c.616A>T p.N206Y | Missense Mutation (SNP) | VAF 20/560 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- PYY | c.170A>G p.N57S | Missense Mutation (SNP) | VAF 13/441 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); called by muse, mutect2
- SFXN1 | c.607G>A p.V203I | Missense Mutation (SNP) | VAF 7/187 reads (4%) | SIFT tolerated (0.37); PolyPhen benign (0.099); called by muse, mutect2
- SMAD3 | c.79G>T p.E27* | Nonsense Mutation (SNP) | VAF 30/914 reads (3%) | called by muse, mutect2
- SPART | c.736G>T p.G246W | Missense Mutation (SNP) | VAF 13/386 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- BOLA1 | c.183G>A p.P61= | Silent (SNP) | VAF 18/344 reads (5%) | catalogued as rs782537871, COSV64967015; called by muse, mutect2
- COL22A1 | c.18G>A p.G6= | Silent (SNP) | VAF 16/592 reads (3%) | catalogued as COSV57326547; called by muse, mutect2
- FOXF1 | c.960C>T p.N320= | Silent (SNP) | VAF 28/786 reads (4%) | catalogued as COSV52285969; called by muse, mutect2
- KIF26B | c.4926C>T p.S1642= | Silent (SNP) | VAF 18/490 reads (4%) | catalogued as COSV100832556; called by muse, mutect2
- MCHR2 | c.423G>A p.L141= | Silent (SNP) | VAF 7/168 reads (4%) | catalogued as rs924356830; called by muse, mutect2
- MPRIP | c.2164-4220G>T | Intron (SNP) | VAF 19/490 reads (4%) | called by muse, mutect2
- NR2F2-AS1 | n.931C>T | RNA (SNP) | VAF 16/406 reads (4%) | catalogued as rs1447546221; called by muse, mutect2
- PLEKHG5 | c.1654-40G>A | Intron (SNP) | VAF 30/634 reads (5%) | catalogued as rs1292380917; called by muse, mutect2
- PTPRC | c.658+36C>T | Intron (SNP) | VAF 17/482 reads (4%) | catalogued as rs1175204179, COSV61418971; called by muse, mutect2
- TECPR2 | c.*753G>A | 3'UTR (SNP) | VAF 30/695 reads (4%) | catalogued as rs954861956; called by muse, mutect2
- ZNF252P | n.759T>C | RNA (SNP) | VAF 10/287 reads (3%) | called by muse, mutect2
